Surgical pathology report (de-identified scan), TCGA case TCGA-09-2056, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-2056-01B (Primary Tumor).

[page 1 of 4]
FINAL PATHOLOGIC DIAGNOSIS

A. Adnexa, left, salpingo-oophorectomy:

1. Ovary with serous carcinoma, high-grade; see comment.
2. Fallopian tube with no significant pathologic abnormality.

B. Adnexa, right, salpingo-oophorectomy:

1. Ovary with serous carcinoma, high-grade; see comment.
2. Fallopian tube with serous carcinoma, high-grade; see comment.

C. Uterus and cervix, total abdominal hysterectomy:

1. Cervix with no significant pathologic abnormality.
2. Uterus with:

- Inactive endometrium with benign polyp.
- Myometrium with leiomyoma.
- Serosa with no significant pathologic abnormality.

D. Lymph nodes, right pelvic, biopsy: No tumor identified in nine lymph nodes (0/9).

E. Lymph nodes, right common iliac, biopsy: No tumor identified in six lymph nodes (0/6).

F. Lymph nodes, right periaortic, biopsy: No tumor identified in four lymph nodes (0/4).

G. Lymph nodes, left pelvic, biopsy: No tumor identified in nine lymph nodes (0/9).

H. Lymph nodes, left common iliac, biopsy: No tumor identified in two lymph nodes (0/2).

Page 1 of 5

I. Lymph nodes, left periaortic, biopsy: No tumor identified in one lymph node (0/1).

J. Omentum, biopsy: Fibroadipose tissue with no significant pathologic abnormality, no tumor.

K. Omentum, biopsy: Fibroadipose tissue with no significant pathologic abnormality, no tumor.

L. Omentum, biopsy: Fibroadipose tissue with no significant pathologic abnormality, no tumor.

M. Sigmoid adhesion, biopsy: Inflamed granulation tissue consistent with adhesions, no tumor.

COMMENT:

Ovarian Tumor Synoptic Comment

- **Location of tumor:** Bilateral.
- **Type of tumor:** Serous.
- **Grade of tumor:** 3.
- **Size of tumor:** Left ovary and tube: 15 cm; right ovary and tube: 12 cm.
- **Surface of ovary:** Smooth.
- **Condition of capsule:** Intact.
- **Cut surface:** Solid and cystic, mainly solid.
- **Necrosis:** Focal.
- **Lymphatic/vascular invasion:** Not identified.
- **Sites of metastases in pelvis:** Fallopian tube.
- **Size of largest pelvic metastasis** is 0.5 cm.
- **Pelvic lymph nodes:** Negative.

[page 2 of 4]
- [REDACTED]
- Total number of nodes examined: 26.
- **Sites of metastases in abdomen:** None.
- **Para-aortic lymph nodes:** Negative.
- Total number of nodes examined: 5.
- **Peritoneal cytology:** Positive (Cytology CoPath accession number: [REDACTED])
- **Other findings:** None.
- **FIGO stage:** IIC.
- **AJCC stage:** pT2cN0MX.

[REDACTED] and [REDACTED] have reviewed the case (parts A and B) and agree with the above diagnoses.

Specimen(s) Received

A: Left adnexa (FS)
B: Right adnexa (fresh)
C: Uterus and cervix (fresh)
D: Right pelvic lymph node
E: Right common iliac lymph nodes
F: Right periaortic lymph nodes
G: Left pelvic lymph nodes
H: Left common iliac lymph nodes
I: Left periaortic lymph nodes
J: Omentum #1
Page 2 of 5

K: Omentum #2
L: Omentum #3
M: Sigmoid adhesion

Intraoperative Diagnosis

FS1 (A) Left adnexa, salpingo-oophorectomy: Adenocarcinoma, favor ovarian primary. (Dr. [REDACTED])

B. Right adnexa, salpingo-oophorectomy: Grossly similar to left ovarian tumor. Gross examination only. (Dr. [REDACTED])

C. Uterus and cervix, hysterectomy: Endometrial polyp. Gross examination only. (Dr. [REDACTED])

Clinical History

The patient is a [REDACTED], G2, P2, with bilateral 10-cm adnexal masses. [REDACTED] is noted to have an elevated CA-125 at 3,410. [REDACTED] also has a history of right breast cancer, status post chemotherapy and surgery in [REDACTED]. [REDACTED] undergoes bilateral salpingo-oophorectomy and total abdominal hysterectomy.

Gross Description

The specimen is received in 13 parts, each labeled with the patient's name and medical record number. Parts A-C are received fresh. Parts D-M are received in formalin. Part A, labeled "left adnexa," consists of an ovary with attached fallopian tube weighing 327.5 grams. The ovary is replaced by a mass and measures 15 x 10.5 x 5.5 cm, and the fallopian tube measures 10 cm in length x 0.5 cm in diameter. Gross photographs are taken. The external surface of the ovary is noted to be smooth, tan-white-gray and shiny. No surface adhesions, solid tumor or papillary growth, or implants are noted. The tumor capsule is intact. Upon sectioning, the cut surface of this nodule appears to be yellow-orange. Sectioning of the tumor reveals 70% solid growth with 30% cystic area. The cystic area is multiloculated and contains yellow serous fluid. The solid portion of the ovary is yellow, lobulated, firm, with punctate areas of hemorrhage. The cystic area is also noted to contain some areas of hemorrhage. The interior of the cyst is noted to contain papillary excrescences. A portion of the specimen is submitted for frozen section diagnosis 1, with the remnant submitted in cassette A14. The attached fallopian tube and fimbriae appear grossly

[page 3 of 4]
unremarkable. However, a small, white-tan nodule measuring 0.3 x 0.2 x 0.2 cm is visible on the surface of the mesosalpinx. An additional nodule measuring 0.4 x 0.4 x 0.3 cm is palpable within the mesosalpinx. Representative sections are submitted as follows:

Cassettes A1-A8: Representative sections of tumor (solid)

Cassettes A9-A10: Representative sections of tumor (cystic).

Cassette A11: Fimbria.

Cassette A12: Fallopian tube.

Cassette A13: Mesosalpinx, with two nodules.

Cassette A14: Frozen section remnant. [REDACTED]

Part B, labeled "right adnexa," consists of an ovary with attached fallopian tube weighing 296 grams. The ovary is replaced by a mass and measures 12 x 9.5 x 6.5 cm. The tube measures 9 cm in length x 0.5 cm in diameter. A portion of the specimen is sent for Oncotech, and sample tissue is taken for ovarian tumor banking. The surface of the ovary is noted to be tan-white-gray and smooth, without adhesions, solid tumor, papillary growth or implants. The tumor capsule appears to be intact. Sectioning of the ovary reveals an 80% solid, 20% cystic mass. The solid areas are tan-white-yellow and firm/rubbery, and also contain soft and papillary areas. Small areas of hemorrhage are noted in the solid areas. No obvious areas of necrosis are noted. The cystic areas within the tumor contain papillary excrescences and a yellow serous fluid. The cystic area is noted to be unilocular. The fimbriae are grossly unremarkable. However, approximately 2.2 cm from the fimbriae, a hard nodule is palpable within the fallopian tube, measuring 1 x 0.8 x 0.7 cm. Representative sections are submitted as follows:

Page 3 of 5

Cassettes B1-B6: Representative sections of tumor (solid).

Cassette B7: Representative sections of tumor (cystic).

Cassette B8: Fimbriae.

Cassette B9: Fallopian tube, including nodule (entirely submitted). [REDACTED]

Part C, labeled "uterus, cervix," consists of a uterus weighing 72 grams and measuring 4.5 cm cornu to cornu, 9 cm superior to inferior, 3.5 cm anterior to posterior. The uterine cavity sounds to 7.5 cm. The cervix measures 2.6 cm in length x 2.5 cm in width. The os is pinpoint and 0.3 cm in diameter. The anterior surface is inked blue; the posterior surface is inked black. The specimen is bivalved. Normal tissue is taken for ovarian tumor banking. The serosa is tan-pink and smooth, with no masses or nodules identified. The ectocervix is grossly unremarkable, with the exception of some brown discoloration. A tan-brown polyp is seen at the uterine fundus on the posterior side, slightly to the right, measuring 1.8 x 1.5 x 1.3 cm. Serial sectioning of the uterine body perpendicular to the long axis reveals a single, tan-white, homogeneous, rubbery, round leiomyoma measuring 2.7 x 2.7 x 2.5 cm. No areas of hemorrhage or necrosis are noted within the leiomyoma. Representative sections are submitted as follows:

Cassette C1: Anterior cervix.

Cassette C2: Posterior cervix.

Cassette C3: Anterior lower uterine segment.

Cassette C4: Posterior lower uterine segment.

Cassette C5: Anterior endometrium.

Cassette C6: Posterior endometrium.

Cassette C7: Posterior myometrium.

Cassettes C8-C11: Fundic polyp, entirely submitted.

Cassettes C12-C13: Representative sections of leiomyoma. [REDACTED]

Part D is additionally labeled "right pelvic lymph nodes," and consists of multiple bloody, soft, firm, brown-yellow-tan tissue fragments measuring 6 x 4.5 x 1.5 cm in aggregate. Nine candidate lymph nodes are found ranging between 0.5 to 2.7 cm. The specimen is submitted as follows:

Cassettes D1-D2: One bisected lymph node, entirely submitted.

Cassette D3: One bisected lymph node, entirely submitted

Cassette D4: Seven candidate lymph nodes.

Remaining fatty tissue is returned to the container. [REDACTED]

Part E is additionally labeled "right common iliac lymph nodes," and consists of multiple bloody,

[page 4 of 4]
[REDACTED]

yellow-tan, soft, firm tissue fragments measuring 5.2 x 2.5 x 1.2 cm in aggregate. Six candidate lymph nodes are found ranging from 0.8 to 1.6 cm. The specimen is submitted as follows:

Cassette E1: Five candidate lymph nodes.

Cassette E2: One bisected lymph node.

Remaining fatty tissue is returned to the container. [REDACTED]

Part F is additionally labeled "right periaortic lymph node," and consists of multiple bloody, yellow-tan, soft, firm tissue fragments measuring 3.5 x 2 x 1 cm in aggregate. Five candidate lymph nodes are found ranging from 0.7 to 1.5 cm. The specimen is submitted as follows:

Cassette F1: One bisected lymph node.

Cassette F2: Four candidate lymph nodes.

Remaining fatty tissue is returned to the container. [REDACTED]

Part G is additionally labeled "left pelvic lymph nodes," and consists of multiple bloody, yellow-tan, soft, firm tissue fragments measuring 6.7 x 4.5 x 2 cm in aggregate. Nine candidate lymph nodes are found ranging from 0.5 to 2.4 cm. The specimen is submitted as follows:

Cassettes G1-G2: One bisected lymph node.

Cassette G3: Five candidate lymph nodes.

Cassette G4: Three candidate lymph nodes.

Remaining fatty tissue is returned to the container. [REDACTED]

Part H is additionally labeled "left common iliac lymph nodes," and consists of multiple bloody,

Page 4 of 5

yellow-tan, soft, firm tissue fragments measuring 3.2 x 2.9 x 1.2 cm in aggregate. Two candidate lymph nodes are found ranging from 0.5 to 1.4 cm. They are entirely submitted in cassette H1. The remaining fatty tissue is returned to the container. [REDACTED]

Part I is additionally labeled "left periaortic lymph nodes," and consists of multiple bloody, yellow-tan, soft, firm tissue fragments measuring 2.8 x 2 x 0.7 cm in aggregate. One candidate lymph node is found and is entirely submitted in cassette I1. The remaining fatty tissue is returned to the container. [REDACTED]

Part J is additionally labeled "omentum #1," and consists of a single soft, firm, roughly rectangular sheet of yellow fatty tissue measuring 15 x 7 x 1.5 cm. The specimen is palpated and is serially sectioned at 1-cm intervals. There are no lesions, nodules or candidate lymph nodes found.

Representative sections are submitted in cassettes J1-J2. [REDACTED]

Part K is additionally labeled "omentum #2," and consists of a single soft, firm, roughly rectangular sheet of yellow fatty tissue measuring 12.5 x 9 x 1.6 cm. The specimen is palpated and is serially sectioned at 1-cm intervals. There are no lesions, nodules or candidate lymph nodes found.

Representative sections are submitted in cassettes K1-K2. [REDACTED]

Part L is additionally labeled "omentum #3," and consists of a single soft, firm, roughly rectangular sheet of yellow fatty tissue measuring 13 x 11 x 1 cm. The specimen is palpated and serially sectioned at 1-cm intervals. No lesions, nodules or candidate lymph nodes are found.

Representative sections are submitted in cassettes L1-L2. [REDACTED]

Part M is additionally labeled "sigmoid adhesion," and consists of two firm, irregular, bloody red tissue fragments measuring 0.7 x 0.6 x 0.2 cm in aggregate. The specimen is entirely submitted in cassette M1. [REDACTED]

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

Source: NCI Genomic Data Commons file a5069a21-e6cd-4d23-b858-b0e7a0415706 (TCGA-09-2056.67BDB457-CFB8-4052-BD33-BFF86C736910.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).